Somatic mutation profile of tumor specimen 0DL6S0 from CCDI case PBBZAL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.0 years (6,586 days).
Specimen 0DL6S0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac978d83-b285-4562-a2b3-2681e792c9cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DL6RK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b16cace6-9208-47dc-867f-d2f6e788b104

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 2, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLTC | c.4744G>A p.V1582I | Missense Mutation (SNP) | VAF 266/868 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.151); catalogued as rs780462309; called by muse, mutect2, varscan2
- ZDBF2 | c.5561G>A p.R1854H | Missense Mutation (SNP) | VAF 42/742 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.224); catalogued as rs373852008, COSV65626819; called by muse, mutect2
- OSBPL3 | c.765C>G p.I255M | Missense Mutation (SNP) | VAF 96/1210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRIN2D | c.2619G>A p.L873= | Silent (SNP) | VAF 21/366 reads (6%) | catalogued as rs1569074549; called by muse, mutect2
- SIM2 | c.733C>T p.L245= | Silent (SNP) | VAF 63/466 reads (14%) | catalogued as COSV51770575; called by muse, mutect2, varscan2
- CCSER1 | c.1724+71T>A | Intron (SNP) | VAF 27/219 reads (12%) | called by muse, mutect2, varscan2
- HOXD11 | c.*1G>C | 3'UTR (SNP) | VAF 68/443 reads (15%) | catalogued as COSV99983341; called by muse, mutect2, varscan2
- IGF2BP3 | c.*40C>T | 3'UTR (SNP) | VAF 186/734 reads (25%) | catalogued as COSV99325725; called by muse, mutect2, varscan2
